Somatic mutation profile of tumor specimen TCGA-BL-A3JM-01A (aliquot TCGA-BL-A3JM-01A-12D-A21A-08) from TCGA case TCGA-BL-A3JM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 63.0 years (23,000 days).
Specimen TCGA-BL-A3JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fe1287f-5557-407e-8952-d651698ace97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BL-A3JM-11A (Solid Tissue Normal), aliquot TCGA-BL-A3JM-11A-31D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76f7c595-6b1a-47d5-9504-c94d63809d5a

The open-access MAF lists 241 somatic variants for this specimen: 165 protein-altering or splice-affecting, 62 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 62, Nonsense Mutation 15, Intron 6, Splice Site 4, RNA 3, Splice Region 2, 5'UTR 2, Frame Shift Del 2, 5'Flank 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as rs886043247, CM030506, COSV57295964, COSV99927064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 149/178 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.1862T>C p.L621P | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59392681; called by muse, mutect2, varscan2
- ABCA8 | c.1928-1G>A p.X643_splice | Splice Site (SNP) | VAF 20/92 reads (22%) | catalogued as COSV52193241; called by muse, mutect2, varscan2
- ACP3 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV60488715; called by muse, mutect2, varscan2
- ALCAM | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV60255241; called by muse, mutect2, varscan2
- ANKRD12 | c.6124G>A p.E2042K | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50850278; called by muse, mutect2, varscan2
- ANO3 | c.1963T>C p.Y655H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56809298; called by muse, mutect2, varscan2
- AP002748.5 | c.927C>G p.I309M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV59151891; called by muse, mutect2, varscan2
- ARHGAP35 | c.2479G>A p.G827R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749271027, COSV68333194; called by muse, mutect2, varscan2
- ARID1A | c.5404G>T p.E1802* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100249980; called by muse, mutect2, varscan2
- ARID1A | c.6103G>A p.E2035K | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV61389491; called by muse, mutect2, varscan2
- ARID1A | c.6564G>T p.Q2188H | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61389499; called by muse, mutect2, varscan2
- ARPP21 | c.500T>G p.L167R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51808628; called by muse, mutect2, varscan2
- ARX | c.1090A>T p.R364W | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66875820; called by muse, mutect2, varscan2
- C12orf42 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.319); catalogued as COSV59391129; called by muse, mutect2, varscan2
- CACHD1 | c.543C>A p.N181K | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as COSV51560239; called by muse, mutect2
- CCNL2 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 40/108 reads (37%) | catalogued as COSV68767011; called by muse, mutect2, varscan2
- CD5L | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs780866786, COSV63822762; called by muse, mutect2, varscan2
- CDC73 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV66470181, COSV66470515; called by muse, mutect2, varscan2
- CDCA2 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV57948707, COSV57949762; called by muse, mutect2, varscan2
- CDHR5 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV62764042; called by muse, mutect2, varscan2
- CDKN1B | c.242_243insTTCT p.K81Nfs*45 | Frame Shift Ins (INS) | VAF 75/161 reads (47%) | catalogued as COSV57431646; called by mutect2, pindel, varscan2
- CELF4 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs769258928, COSV58466701; called by muse, mutect2, varscan2
- CEP350 | c.2239C>T p.Q747* | Nonsense Mutation (SNP) | VAF 58/168 reads (35%) | catalogued as COSV62606217; called by muse, mutect2, varscan2
- CFAP61 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as rs774135652, COSV55648169; called by muse, mutect2, varscan2
- CLVS2 | c.373A>T p.N125Y | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51569149; called by muse, mutect2, varscan2
- CMYA5 | c.5583G>T p.L1861F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV71404964; called by muse, mutect2, varscan2
- COL5A1 | c.5393C>T p.T1798M | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs761036527, COSV65673586; called by muse, mutect2, varscan2
- CRACD | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1309977766, COSV51731882; called by muse, varscan2
- CSDE1 | c.2251G>A p.D751N (on ENST00000358528 / NM_001007553.3; = p.D720N on NM_007158.6) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV54759249, COSV54760740; called by muse, mutect2, varscan2
- CSNK1G2 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55335844, COSV55339935; called by muse, mutect2, varscan2
- DBP | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV50034252; called by muse, mutect2, varscan2
- DCAF7 | c.72G>C p.W24C | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59007803; called by muse, mutect2, varscan2
- DEPDC5 | c.3578G>A p.W1193* (on ENST00000400246; = p.W1262* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 90/137 reads (66%) | catalogued as COSV56695877; called by muse, mutect2, varscan2
- DPP10 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59730117; called by muse, mutect2, varscan2
- DPP3 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as COSV64758106; called by muse, mutect2, varscan2
- DUS1L | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1249952008, COSV57651479; called by muse, mutect2, varscan2
- DUSP26 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.253); catalogued as COSV56362545; called by muse, mutect2, varscan2
- DUSP7 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56589749; called by muse, mutect2, varscan2
- DYNC1H1 | c.6054G>C p.M2018I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64142785; called by muse, mutect2, varscan2
- EIF4G3 | c.3490C>G p.Q1164E | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV51694644; called by muse, mutect2, varscan2
- EOGT | c.1201G>A p.D401N (on ENST00000383701 / NM_001278689.2; = p.D317N on NM_173654.3) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.376); catalogued as COSV55154012; called by muse, mutect2, varscan2
- EVI5L | c.1113G>C p.K371N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV54488872; called by muse, mutect2, varscan2
- FAM111B | c.1685G>A p.W562* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV59113003; called by muse, mutect2, varscan2
- FAM71A | c.133A>T p.I45L | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV54237351; called by muse, mutect2, varscan2
- FBXL7 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 114/440 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV73494589; called by muse, mutect2, varscan2
- FLT3 | c.2340G>C p.L780F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV54042403, COSV54070930; called by muse, mutect2, varscan2
- FMO3 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1464657042, COSV63008657, COSV63008791; called by muse, mutect2, varscan2
- FREM1 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748464182, COSV66530345; called by muse, mutect2, varscan2
- FRY | c.4193C>G p.S1398C | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as COSV66580494; called by muse, mutect2, varscan2
- FSTL5 | c.1418A>G p.Q473R | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as rs781592052, COSV60231467; called by muse, mutect2, varscan2
- FUS | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.036); catalogued as COSV54219832; called by muse, mutect2, varscan2
- GALNT2 | c.1185C>G p.F395L | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV64194651, COSV64197639; called by muse, mutect2, varscan2
- GDF6 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV54627927; called by muse, mutect2, varscan2
- GPR108 | c.1300+1G>A p.X434_splice (on ENST00000264080 / NM_001080452.1; = p.X192_splice on NM_020171.2) | Splice Site (SNP) | VAF 15/16 reads (94%) | catalogued as rs768162199, COSV51187699; called by muse, mutect2, varscan2
- GPR32 | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 67/84 reads (80%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs752215632, COSV54514954, COSV54515667; called by muse, mutect2, varscan2
- GPX3 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as rs776064760, COSV100161806; called by muse, varscan2
- GPX3 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as COSV59310423; called by muse, varscan2
- H1-4 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56800081, COSV99175236; called by muse, mutect2
- IL10RA | c.689-1G>T p.X230_splice | Splice Site (SNP) | VAF 118/148 reads (80%) | catalogued as COSV57142223; called by muse, mutect2, varscan2
- INPP5A | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1305513647, COSV61253381; called by muse, mutect2, varscan2
- IQCN | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV66578049; called by muse, varscan2
- IRX2 | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57413846; called by muse, mutect2, varscan2
- JRKL | c.274G>C p.A92P | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV53595569; called by muse, mutect2, varscan2
- KIF1C | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 83/472 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57907560; called by muse, mutect2, varscan2
- KLF5 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV66613759; called by muse, mutect2, varscan2
- KLHL22 | c.1146C>G p.I382M | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); catalogued as COSV61023011; called by muse, mutect2, varscan2
- KMT2A | c.4330G>C p.E1444Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV63292703, COSV63292818; called by muse, mutect2
- L3MBTL4 | c.123T>G p.S41R | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV53141198; called by muse, varscan2
- LPL | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as CM921018, COSV60933055; called by muse, mutect2, varscan2
- LRFN4 | c.1630del p.A544Pfs*80 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | catalogued as rs1555021490; called by mutect2, pindel, varscan2
- MACF1 | c.19254G>T p.Q6418H (on ENST00000372915; = p.Q4463H on NM_012090.5) | Missense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as COSV57145091; called by muse, mutect2, varscan2
- MAP4 | c.2369A>T p.K790M | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53142804; called by muse, mutect2, varscan2
- MDN1 | c.4654G>A p.E1552K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV65530582; called by muse, mutect2, varscan2
- MED1 | c.4576C>G p.H1526D | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56126214, COSV56128586; called by muse, mutect2, varscan2
- MICAL2 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV56326620; called by muse, mutect2, varscan2
- MIEN1 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.38); catalogued as COSV54083380; called by muse, mutect2, varscan2
- MLLT3 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV63502843; called by muse, mutect2, varscan2
- MLST8 | c.73C>G p.R25G | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57029446, COSV57031320; called by muse, mutect2, varscan2
- MOGAT3 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 81/111 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as rs759678400, COSV56173938, COSV56177686; called by muse, mutect2, varscan2
- MUC16 | c.37958G>A p.R12653K | Missense Mutation (SNP) | VAF 323/390 reads (83%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs1464185484, COSV67495293; called by muse, mutect2, varscan2
- MUC16 | c.15193T>G p.S5065A | Missense Mutation (SNP) | VAF 69/89 reads (78%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV67495297; called by muse, mutect2, varscan2
- MYH4 | c.1009-1G>C p.X337_splice | Splice Site (SNP) | VAF 29/153 reads (19%) | catalogued as rs1342606358, COSV55126646; called by muse, mutect2, varscan2
- MYO10 | c.3740T>C p.M1247T | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.289); catalogued as rs537885151, COSV57030286; called by muse, mutect2, varscan2
- NOP16 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs759109610, COSV51258012, COSV99220871; called by muse, mutect2, varscan2
- NUP93 | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV57434221; called by muse, mutect2, varscan2
- NUP98 | c.3839G>T p.W1280L (on ENST00000359171 / NM_001365126.1; = p.W1263L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61438844; called by muse, mutect2, varscan2
- OR1L3 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs200110272, COSV59169419; called by muse, mutect2, varscan2
- OR2G3 | c.22T>A p.S8T | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV60683295; called by muse, mutect2, varscan2
- OR4C46 | c.101T>G p.I34S | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV60221282; called by muse, mutect2, varscan2
- OR5D18 | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 51/128 reads (40%) | catalogued as rs1239546567, COSV100450946; called by muse, mutect2, varscan2
- OR8A1 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV52510521, COSV99420501; called by muse, mutect2, varscan2
- PANK2 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV57256354; called by muse, varscan2
- PAPOLA | c.1765G>A p.G589S | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV53485622; called by muse, mutect2, varscan2
- PAX4 | c.567C>A p.F189L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV58389196, COSV58391359; called by muse, mutect2, varscan2
- PBX2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as rs773626213, COSV66708712; called by muse, mutect2, varscan2
- PDE3A | c.1094C>G p.S365C | Missense Mutation (SNP) | VAF 69/119 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV62983237; called by muse, mutect2, varscan2
- PGD | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54623279; called by muse, mutect2, varscan2
- PHACTR2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); catalogued as rs767531493, COSV59859551; called by muse, mutect2, varscan2
- PHTF1 | c.1769T>G p.I590S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63368904; called by muse, mutect2, varscan2
- PIDD1 | c.1564C>A p.Q522K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57195116; called by muse, mutect2, varscan2
- PITPNM1 | c.2670G>T p.E890D | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV54161907; called by muse, mutect2, varscan2
- PIWIL1 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs751456474, COSV55352195; called by muse, mutect2, varscan2
- PLAG1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770460305, COSV57615356; called by muse, mutect2, varscan2
- PLEKHH3 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 83/393 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52217386; called by muse, mutect2, varscan2
- PLIN3 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55737220; called by muse, mutect2, varscan2
- POC1A | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV56593728; called by muse, mutect2, varscan2
- POTEM | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV69152208, COSV69155162; called by muse, varscan2
- PPARGC1A | c.1792A>C p.R598= | Splice Region (SNP) | VAF 14/42 reads (33%) | catalogued as COSV53533825; called by muse, mutect2, varscan2
- PRDM5 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV53357234; called by muse, mutect2, varscan2
- PROM1 | c.127A>C p.T43P | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71700009; called by muse, mutect2, varscan2
- PTPRD | c.3817C>T p.P1273S | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV61982565; called by muse, mutect2, varscan2
- PTPRD | c.3578C>T p.A1193V | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV61982586; called by muse, mutect2, varscan2
- PTPRO | c.2040G>C p.K680N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.236); catalogued as rs1385507658, COSV55523346, COSV99839871; called by muse, mutect2, varscan2
- RBM26 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as COSV57400048; called by muse, mutect2, varscan2
- RBM47 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV55943672; called by muse, mutect2, varscan2
- RP1 | c.2890A>G p.I964V | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1291795198, COSV55127251; called by muse, mutect2, varscan2
- RSF1 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV57844529, COSV57845934; called by muse, mutect2, varscan2
- SKAP2 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61728080; called by muse, mutect2, varscan2
- SLC25A27 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV51499434; called by muse, mutect2, varscan2
- SLC4A5 | c.2326G>T p.A776S | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.8); PolyPhen benign (0.174); catalogued as rs758099519, COSV61033141; called by muse, mutect2, varscan2
- SLC9C2 | c.1342G>C p.A448P | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV62949654; called by muse, varscan2
- SMYD4 | c.2064G>C p.E688D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as COSV59713789; called by muse, varscan2
- SPATA19 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100141083, COSV54485057; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | PolyPhen probably damaging (1); catalogued as COSV60320356, COSV60350424; called by muse, mutect2, varscan2
- STIMATE | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61891703; called by muse, mutect2, varscan2
- SUCO | c.2041C>G p.L681V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201179674, COSV55271543; called by muse, mutect2, varscan2
- SV2B | c.46A>G p.S16G | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); catalogued as COSV57702276; called by muse, mutect2, varscan2
- SYBU | c.949G>C p.E317Q (on ENST00000276646 / NM_001099754.2; = p.E316Q on NM_017786.6) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52623102; called by muse, mutect2, varscan2
- SYNE2 | c.20293A>G p.M6765V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762082013, COSV59971016; called by muse, varscan2
- TAZ | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 228/291 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV54797448; called by muse, mutect2, varscan2
- TBX5 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 137/263 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557183241, COSV59862979; called by muse, mutect2, varscan2
- TLCD4 | c.14C>G p.T5R | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV64633597; called by muse, mutect2, varscan2
- TLE5 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as rs751340520, COSV55592853; called by muse, mutect2, varscan2
- TMPRSS2 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV59827619; called by muse, varscan2
- TNS1 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as rs1271417746, COSV50771642; called by muse, mutect2, varscan2
- TRIO | c.8627G>A p.R2876H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781136104, COSV59992531; called by muse, mutect2, varscan2
- TSC22D1 | c.2821G>A p.G941R | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1295268132, COSV71776442; called by muse, mutect2, varscan2
- TTN | c.98580G>C p.E32860D (on ENST00000591111; = p.E25436D on NM_003319.4) | Missense Mutation (SNP) | VAF 42/113 reads (37%) | PolyPhen benign (0.013); catalogued as COSV60360106; called by muse, mutect2, varscan2
- WDR36 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV72411501; called by muse, mutect2, varscan2
- ZAN | c.4680C>A p.F1560L | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV61816956; called by muse, mutect2, varscan2
- ZFHX4 | c.5044C>G p.Q1682E | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.109); catalogued as COSV50655199; called by muse, mutect2, varscan2
- ZNF214 | c.263A>C p.Q88P | Missense Mutation (SNP) | VAF 151/355 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV53483777; called by muse, mutect2, varscan2
- ZNF335 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs200963656, COSV100532555; called by muse, mutect2, varscan2
- ZNF426 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV53470692; called by muse, mutect2, varscan2
- ZNF626 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV101656935, COSV74130982; called by muse, mutect2, varscan2
- ARHGAP32 | c.2987C>G p.S996* (on ENST00000310343 / NM_001378025.1; = p.S647* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- COL5A1 | c.4199C>A p.P1400H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DACH1 | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- DSEL | c.1575G>A p.W525* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | called by muse, mutect2, varscan2
- GDF6 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, mutect2
- GRM1 | c.2658C>T p.A886= | Splice Region (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- HESX1 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2
- HNF1B | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IQCN | c.144_145del p.K49Sfs*149 | Frame Shift Del (DEL) | VAF 62/214 reads (29%) | called by pindel, varscan2
- KRT33B | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 20/447 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- NCKAP5L | c.2642C>G p.S881* | Nonsense Mutation (SNP) | VAF 107/187 reads (57%) | called by muse, mutect2, varscan2
- PNLDC1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 64/191 reads (34%) | called by muse, mutect2, varscan2
- PYCR1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- SEMA3A | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- SKIDA1 | c.2002G>T p.E668* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- TPTE | c.868T>G p.Y290D (on ENST00000618007 / NM_199261.4; = p.Y272D on NM_199259.4) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF84 | c.2076C>G p.F692L | Missense Mutation (SNP) | VAF 99/195 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCC10 | c.966C>T p.H322= (on ENST00000372530 / NM_001198934.2; = p.H279= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs145760020; called by muse, mutect2, varscan2
- ABCC9 | c.1581T>C p.S527= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV53986931; called by muse, mutect2, varscan2
- ABCG8 | c.1404C>T p.I468= | Silent (SNP) | VAF 70/184 reads (38%) | catalogued as COSV55396959; called by muse, mutect2, varscan2
- ALG5 | c.381T>C p.Y127= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV53507469; called by muse, mutect2, varscan2
- ALPP | c.825C>G p.L275= | Silent (SNP) | VAF 79/223 reads (35%) | catalogued as COSV67398130; called by muse, mutect2, varscan2
- ANO1 | c.2433C>T p.F811= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV62450448; called by muse, mutect2, varscan2
- APTX | c.489C>T p.S163= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV58930581; called by muse, varscan2
- ARHGEF10 | c.1326G>A p.R442= (on ENST00000398564; = p.R417= on NM_014629.4) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs765806365, COSV50679482; called by muse, mutect2, varscan2
- ASAP3 | c.594C>G p.L198= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV60878173; called by muse, mutect2, varscan2
- ATP13A3 | c.3072T>G p.G1024= | Silent (SNP) | VAF 44/56 reads (79%) | catalogued as rs201703070, COSV55461411, COSV55462487; called by muse, varscan2
- BIN2 | c.150C>T p.F50= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs989926935, COSV57208167; called by muse, mutect2, varscan2
- BLOC1S2 | c.156G>A p.L52= | Silent (SNP) | VAF 91/290 reads (31%) | catalogued as COSV58399060; called by muse, mutect2, varscan2
- BRD2 | c.714C>T p.L238= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV66374537; called by muse, mutect2, varscan2
- CCR6 | c.546T>G p.T182= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as COSV59476280; called by muse, mutect2, varscan2
- CD6 | c.939G>A p.E313= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs371204521; called by muse, mutect2, varscan2
- CDC20B | c.1509G>A p.R503= (on ENST00000381375 / NM_001170402.1; = p.R499= on NM_152623.2) | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV57057663; called by muse, mutect2, varscan2
- CLEC4M | c.1107G>A p.A369= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as rs144974332; called by muse, mutect2
- CNTNAP2 | c.2151C>T p.Y717= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV62260869; called by muse, mutect2, varscan2
- COL5A1 | c.5025C>T p.A1675= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs560774273, COSV65674980; called by muse, mutect2, varscan2
- CSMD3 | c.8058C>A p.T2686= (on ENST00000297405 / NM_001363185.1; = p.T2582= on NM_052900.3) | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as COSV52324894, COSV99825550; called by muse, mutect2, varscan2
- DNAH10 | c.6648C>T p.I2216= (on ENST00000409039; = p.I2155= on NM_207437.3) | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV69002271; called by muse, mutect2, varscan2
- DYNC1H1 | c.3435G>A p.Q1145= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV64142777; called by muse, mutect2, varscan2
- EGFL7 | c.603G>A p.Q201= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV58248806; called by muse, mutect2, varscan2
- ETV5 | c.1470C>T p.P490= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as rs151057501; called by muse, mutect2, varscan2
- FABP1 | c.111G>T p.G37= | Silent (SNP) | VAF 123/353 reads (35%) | catalogued as COSV55558555, COSV55559521; called by muse, mutect2, varscan2
- FCHO1 | c.1839G>A p.R613= | Silent (SNP) | VAF 273/329 reads (83%) | catalogued as COSV53185614; called by muse, mutect2, varscan2
- FLNB | c.369C>T p.I123= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as COSV55896199; called by muse, mutect2, varscan2
- GLI1 | c.1170C>T p.D390= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs761285829, COSV57361581; called by muse, mutect2, varscan2
- GLP1R | c.1071C>A p.I357= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs1374533468, COSV64714608, COSV64715675; called by muse, mutect2, varscan2
- GSTA5 | c.402T>G p.P134= | Silent (SNP) | VAF 65/171 reads (38%) | catalogued as COSV52863961; called by muse, mutect2, varscan2
- GUCY2D | c.624G>A p.R208= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV54699065; called by muse, mutect2, varscan2
- HUWE1 | c.402C>T p.V134= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV53364415; called by muse, mutect2, varscan2
- KCNJ11 | c.522C>A p.A174= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV60595594, COSV60595806; called by muse, mutect2, varscan2
- KCNS1 | c.330C>T p.F110= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs772280462; called by muse, mutect2, varscan2
- KIT | c.423A>T p.P141= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV55422649; called by muse, mutect2, varscan2
- KRT79 | c.1476G>C p.G492= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV57941948, COSV57942390; called by muse, mutect2, varscan2
- LRP5 | c.2013C>T p.L671= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1267421437, COSV53723945; called by muse, mutect2, varscan2
- LRRIQ1 | c.1938A>G p.P646= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs765505052, COSV67839008; called by muse, mutect2, varscan2
- MAEL | c.642C>T p.Y214= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV63112662; called by muse, mutect2, varscan2
- MYH1 | c.2019T>C p.F673= | Silent (SNP) | VAF 47/272 reads (17%) | catalogued as COSV56857401; called by muse, mutect2, varscan2
- OBSCN | c.888C>G p.L296= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as COSV52831556; called by muse, mutect2, varscan2
- OR5AC2 | c.225T>G p.T75= | Silent (SNP) | VAF 52/188 reads (28%) | catalogued as COSV100684311, COSV62279447; called by muse, mutect2, varscan2
- OR7G2 | c.126G>A p.P42= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs745701952, COSV59687981; called by muse, mutect2, varscan2
- OTOGL | c.2229G>A p.V743= (on ENST00000547103; = p.V734= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV101509100, COSV72007534; called by muse, mutect2, varscan2
- P3H1 | c.114C>G p.L38= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV52537716; called by muse, mutect2, varscan2
- PGC | c.744C>G p.L248= | Silent (SNP) | VAF 83/185 reads (45%) | catalogued as rs1561880896, COSV62678298; called by muse, mutect2, varscan2
- PLEKHF2 | c.150C>G p.P50= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV59542543; called by muse, mutect2, varscan2
- PNMA8B | c.1125C>T p.V375= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- POGLUT2 | c.555G>A p.Q185= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as COSV65682936, COSV65683056; called by muse, mutect2, varscan2
- PRSS8 | c.420C>T p.L140= | Silent (SNP) | VAF 348/458 reads (76%) | catalogued as COSV54899085; called by muse, mutect2, varscan2
- PRX | c.129C>T p.F43= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- PSMA7 | c.630C>T p.V210= | Silent (SNP) | VAF 145/235 reads (62%) | catalogued as rs1295182046, COSV53383775; called by muse, varscan2
- PTGFRN | c.2550C>T p.I850= | Silent (SNP) | VAF 66/164 reads (40%) | catalogued as rs748854692, COSV67799664; called by muse, mutect2, varscan2
- PTGIR | c.1086C>T p.P362= | Silent (SNP) | VAF 58/75 reads (77%) | catalogued as COSV52193715; called by muse, mutect2, varscan2
- RABEP1 | c.1014A>G p.A338= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV52588658; called by muse, mutect2, varscan2
- RAG1 | c.147G>A p.K49= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV55024296, COSV55026131; called by muse, mutect2, varscan2
- RBM47 | c.807C>T p.F269= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as COSV55943680; called by muse, mutect2, varscan2
- RPL12 | c.375C>G p.L125= | Silent (SNP) | VAF 103/277 reads (37%) | catalogued as COSV55942735; called by muse, mutect2, varscan2
- SPTAN1 | c.6162C>T p.I2054= | Silent (SNP) | VAF 89/248 reads (36%) | catalogued as rs374511397; called by muse, mutect2, varscan2
- TLR9 | c.1710C>T p.F570= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs763720316, COSV62348538; called by muse, mutect2, varscan2
- UBE2M | c.105G>A p.Q35= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV53043369; called by muse, mutect2, varscan2
- ZNF536 | c.3114A>G p.T1038= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs1423955458, COSV62834433; called by muse, mutect2, varscan2
- AK2 | c.94-2808G>A | Intron (SNP) | VAF 17/51 reads (33%) | catalogued as COSV61467302, COSV61470469; called by muse, mutect2, varscan2
- ALAS2 | c.-15-1763G>A | Intron (SNP) | VAF 50/60 reads (83%) | catalogued as COSV100237843, COSV58192047; called by muse, mutect2, varscan2
- ATXN2L | c.*495del | 3'UTR (DEL) | VAF 82/150 reads (55%) | called by mutect2, pindel, varscan2
- GNA13 | c.-1G>C | 5'UTR (SNP) | VAF 59/218 reads (27%) | catalogued as rs775298602, COSV101457388; called by mutect2, varscan2
- LINC00922 | n.858G>A | RNA (SNP) | VAF 41/99 reads (41%) | catalogued as rs769747982; called by muse, mutect2, varscan2
- MACF1 | c.15832-9065C>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs1288838311, COSV57145077; called by muse, varscan2
- MIR1270 | n.10A>T | RNA (SNP) | VAF 18/96 reads (19%) | catalogued as rs1002114695; called by muse, mutect2, varscan2
- MIR20A | n.54G>C | RNA (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- MLLT6 | c.819+213G>A | Intron (SNP) | VAF 69/158 reads (44%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-696A>G | Intron (SNP) | VAF 13/18 reads (72%) | catalogued as COSV53048196; called by muse, mutect2, varscan2
- PARP10 | chr8:143975257 C>T | 3'Flank (SNP) | VAF 95/176 reads (54%) | catalogued as rs781892362, COSV57300196; called by muse, mutect2, varscan2
- RORA | c.196+51302G>A | Intron (SNP) | VAF 54/158 reads (34%) | catalogued as COSV55044806; called by muse, mutect2, varscan2
- TAF8 | chr6:42048667 C>T | 5'Flank (SNP) | VAF 18/48 reads (38%) | catalogued as rs747744173, COSV65897177; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 14/51 reads (27%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
